Somatic mutation profile of tumor specimen 0DFXH7 from CCDI case PBBRND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Tumor cells, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.7 years (1,350 days).
Specimen 0DFXH7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a8f213d-7e9b-40b7-8cd4-3aa46c9881d9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFXF4 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beedace1-e4ee-4ecd-9283-8e8c6f1ad946

The open-access MAF lists 83 somatic variants for this specimen: 45 protein-altering or splice-affecting, 21 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 21, Intron 10, Nonsense Mutation 5, 5'UTR 5, 5'Flank 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACO2 | c.2135C>T p.P712L | Missense Mutation (SNP) | VAF 187/1255 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); catalogued as rs375761361, CM165650; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AFF1 | c.2672C>A p.T891N | Missense Mutation (SNP) | VAF 240/1064 reads (23%) | SIFT tolerated (0.48); PolyPhen benign (0.043); catalogued as COSV57123091; called by muse, mutect2, varscan2
- B4GALNT3 | c.1123G>A p.V375I | Missense Mutation (SNP) | VAF 161/750 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.293); catalogued as COSV56750314; called by muse, mutect2, varscan2
- CHAF1A | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 142/784 reads (18%) | SIFT tolerated (0.97); PolyPhen benign (0.436); catalogued as rs759275580; called by muse, mutect2, varscan2
- DEDD2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 291/680 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.725); catalogued as rs376679587; called by muse, mutect2, varscan2
- DEPTOR | c.1098G>T p.M366I | Missense Mutation (SNP) | VAF 84/408 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.035); catalogued as COSV53813471; called by muse, mutect2, varscan2
- OSBPL9 | c.583-7A>T | Splice Region (SNP) | VAF 85/433 reads (20%) | catalogued as rs781515257; called by muse, mutect2, varscan2
- PEX5L | c.355T>C p.S119P | Missense Mutation (SNP) | VAF 229/1046 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs764146404; called by muse, mutect2, varscan2
- PRDM8 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 86/1167 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as rs758532213; called by muse, mutect2
- RTL9 | c.3922G>T p.E1308* | Nonsense Mutation (SNP) | VAF 312/631 reads (49%) | catalogued as COSV71825884; called by muse, mutect2, varscan2
- SH3PXD2A | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 162/325 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as rs748879853; called by muse, mutect2, varscan2
- SLC35G5 | c.557G>C p.G186A | Missense Mutation (SNP) | VAF 56/1324 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.696); catalogued as COSV99644231; called by muse, mutect2
- TRIM49B | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 299/1559 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as rs771059412; called by muse, mutect2, varscan2
- ZMYM5 | c.838C>A p.R280S | Missense Mutation (SNP) | VAF 106/630 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.082); catalogued as COSV61989976; called by muse, mutect2, varscan2
- ASIC5 | c.1482T>A p.N494K | Missense Mutation (SNP) | VAF 100/732 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASPHD1 | c.1114C>A p.P372T | Missense Mutation (SNP) | VAF 102/640 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CYP39A1 | c.466A>G p.M156V | Missense Mutation (SNP) | VAF 106/665 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- DNAH8 | c.5378A>G p.D1793G | Missense Mutation (SNP) | VAF 68/542 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- DNAJB13 | c.192C>A p.Y64* | Nonsense Mutation (SNP) | VAF 146/853 reads (17%) | called by muse, mutect2, varscan2
- DSC2 | c.1267T>A p.L423M | Missense Mutation (SNP) | VAF 12/387 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM236D | c.181A>T p.R61W (on ENST00000419795 / NM_001348203.1; = p.R57W on NM_001348202.1) | Missense Mutation (SNP) | VAF 361/565 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FOSL2 | c.107T>A p.F36Y | Missense Mutation (SNP) | VAF 70/492 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- FREM2 | c.1769A>T p.D590V | Missense Mutation (SNP) | VAF 40/1114 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GOLGA4 | c.3134C>A p.S1045* | Nonsense Mutation (SNP) | VAF 266/898 reads (30%) | called by muse, mutect2, varscan2
- HIVEP1 | c.4727A>C p.N1576T | Missense Mutation (SNP) | VAF 68/1120 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.012); called by muse, mutect2
- ITGA8 | c.1554C>A p.C518* | Nonsense Mutation (SNP) | VAF 87/481 reads (18%) | called by muse, mutect2, varscan2
- LRAT | c.477C>A p.N159K | Missense Mutation (SNP) | VAF 210/1376 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MAN1A2 | c.648C>G p.N216K | Missense Mutation (SNP) | VAF 53/406 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- MUC12 | c.9283C>G p.L3095V (on ENST00000379442; = p.L2952V on NM_001164462.1) | Missense Mutation (SNP) | VAF 64/2574 reads (2%) | SIFT tolerated (0.62); PolyPhen benign (0.283); called by muse, mutect2
- MVB12A | c.144G>T p.Q48H | Missense Mutation (SNP) | VAF 85/512 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MYO1F | c.3262G>A p.G1088S | Missense Mutation (SNP) | VAF 110/720 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NANP | c.420G>C p.E140D | Missense Mutation (SNP) | VAF 30/948 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); called by muse, mutect2
- NRSN1 | c.348G>C p.K116N | Missense Mutation (SNP) | VAF 156/909 reads (17%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ODF2 | c.82G>T p.V28F (on ENST00000434106 / NM_153433.2; = p.V72F on NM_153432.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/510 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.98); called by mutect2, varscan2
- PLS3 | c.590T>A p.L197* | Nonsense Mutation (SNP) | VAF 19/380 reads (5%) | called by muse, mutect2
- PSD4 | c.2033-2A>T p.X678_splice | Splice Site (SNP) | VAF 76/471 reads (16%) | called by muse, mutect2, varscan2
- PTPRC | c.2233G>T p.A745S | Missense Mutation (SNP) | VAF 88/848 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.378); called by muse, mutect2, varscan2
- RNF6 | c.1214G>T p.R405M | Missense Mutation (SNP) | VAF 176/858 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHANK2 | c.2542A>G p.K848E | Missense Mutation (SNP) | VAF 274/1118 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.191); called by muse, varscan2
- TIGD4 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 160/809 reads (20%) | SIFT tolerated (0.58); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRIO | c.5228A>T p.D1743V | Missense Mutation (SNP) | VAF 128/739 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBASH3A | c.1267G>C p.D423H | Missense Mutation (SNP) | VAF 139/592 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- UGT1A10 | c.759G>T p.L253F | Missense Mutation (SNP) | VAF 152/1707 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.521); called by muse, mutect2
- UNCX | c.1535C>G p.P512R | Missense Mutation (SNP) | VAF 52/1544 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); called by muse, mutect2
- ZWILCH | c.243A>T p.Q81H | Missense Mutation (SNP) | VAF 63/407 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ADGRG6 | c.3501T>C p.G1167= | Silent (SNP) | VAF 142/752 reads (19%) | called by muse, mutect2, varscan2
- GRB7 | c.1584G>C p.T528= | Silent (SNP) | VAF 222/1142 reads (19%) | called by muse, mutect2, varscan2
- HOXB1 | c.531C>G p.A177= | Silent (SNP) | VAF 68/1188 reads (6%) | called by muse, mutect2
- ILDR1 | c.372C>A p.I124= | Silent (SNP) | VAF 90/541 reads (17%) | called by muse, mutect2, varscan2
- KCNH1 | c.1743C>T p.A581= (on ENST00000271751 / NM_172362.3; = p.A554= on NM_002238.4) | Silent (SNP) | VAF 167/997 reads (17%) | called by muse, mutect2, varscan2
- KRT84 | c.363C>A p.G121= | Silent (SNP) | VAF 164/972 reads (17%) | catalogued as COSV99230897; called by mutect2, varscan2
- LRRC40 | c.312G>A p.L104= | Silent (SNP) | VAF 58/1034 reads (6%) | called by muse, mutect2
- MUC3A | c.3153C>T p.S1051= | Silent (SNP) | VAF 30/746 reads (4%) | called by muse, mutect2
- MUC5AC | c.2256G>A p.T752= | Silent (SNP) | VAF 172/775 reads (22%) | catalogued as rs924958544; called by muse, mutect2, varscan2
- PLCB3 | c.1890C>G p.T630= | Silent (SNP) | VAF 129/797 reads (16%) | catalogued as COSV54186264; called by muse, mutect2, varscan2
- PNLIPRP3 | c.234C>A p.I78= | Silent (SNP) | VAF 101/341 reads (30%) | catalogued as COSV65048786; called by muse, mutect2, varscan2
- PROS1 | c.33G>T p.L11= | Silent (SNP) | VAF 46/731 reads (6%) | catalogued as rs372436056; called by muse, mutect2
- RPS6KA2 | c.870G>A p.L290= | Silent (SNP) | VAF 208/1005 reads (21%) | called by muse, mutect2, varscan2
- SIDT1 | c.2268C>T p.A756= | Silent (SNP) | VAF 64/1272 reads (5%) | catalogued as rs371460938; called by muse, mutect2
- TFAP2D | c.507G>T p.G169= | Silent (SNP) | VAF 119/638 reads (19%) | called by muse, mutect2, varscan2
- TTN | c.13545T>C p.G4515= (on ENST00000591111; = p.G3588= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 158/926 reads (17%) | catalogued as rs1261358878; called by muse, varscan2
- TXNDC11 | c.1728T>A p.V576= (on ENST00000356957 / NM_001303447.2; = p.V549= on NM_015914.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 40/671 reads (6%) | called by muse, mutect2
- UBA6 | c.1542T>C p.P514= | Silent (SNP) | VAF 56/509 reads (11%) | called by muse, varscan2
- USP15 | c.2658G>A p.G886= (on ENST00000280377 / NM_001351159.2; = p.G857= on NM_006313.3 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 168/633 reads (27%) | catalogued as rs749030785; called by muse, mutect2, varscan2
- XKR9 | c.1023G>C p.G341= | Silent (SNP) | VAF 26/498 reads (5%) | called by muse, mutect2
- ZAN | c.6930C>T p.S2310= | Silent (SNP) | VAF 52/919 reads (6%) | called by muse, mutect2
- ABCD2 | c.-75A>G | 5'UTR (SNP) | VAF 57/336 reads (17%) | called by muse, mutect2, varscan2
- C4B | c.3155-34A>G | Intron (SNP) | VAF 54/523 reads (10%) | called by muse, mutect2, varscan2
- CACNA1C | c.4829-13C>A | Intron (SNP) | VAF 90/488 reads (18%) | called by mutect2, varscan2
- CBWD1 | c.430+52A>C | Intron (SNP) | VAF 105/630 reads (17%) | called by muse, mutect2, varscan2
- CCDC180 | c.3363+15G>A | Intron (SNP) | VAF 91/499 reads (18%) | called by muse, mutect2, varscan2
- CCDC28B | c.548+97C>T | Intron (SNP) | VAF 190/1076 reads (18%) | called by muse, mutect2, varscan2
- CHN2 | c.1235+9A>T | Intron (SNP) | VAF 60/401 reads (15%) | called by muse, mutect2, varscan2
- DDX19B | chr16:70294972 T>C | 5'Flank (SNP) | VAF 25/377 reads (7%) | called by muse, mutect2
- DIPK2A | c.-17G>C | 5'UTR (SNP) | VAF 14/438 reads (3%) | called by muse, mutect2
- GNL1 | c.1099+10T>G | Intron (SNP) | VAF 236/921 reads (26%) | called by muse, mutect2, varscan2
- MTX3 | c.-23T>A | 5'UTR (SNP) | VAF 32/213 reads (15%) | called by muse, mutect2, varscan2
- MYBPC2 | c.3229-76C>A | Intron (SNP) | VAF 39/180 reads (22%) | called by muse, mutect2, varscan2
- PCDHB2 | c.-48A>G | 5'UTR (SNP) | VAF 9/217 reads (4%) | called by muse, mutect2
- SATB1 | c.1779+504C>T | Intron (SNP) | VAF 29/154 reads (19%) | catalogued as rs1401910477; called by muse, mutect2, varscan2
- SMC3 | c.-78T>A | 5'UTR (SNP) | VAF 47/172 reads (27%) | called by muse, mutect2, varscan2
- TOR1A | chr9:129824147 C>A | 5'Flank (SNP) | VAF 102/360 reads (28%) | called by muse, mutect2
- ZMYND10 | c.700+33G>A | Intron (SNP) | VAF 51/629 reads (8%) | called by muse, mutect2
